Gene-level copy-number profile of tumor specimen ALCH-B2TK-TTP1-A from ALCHEMIST case ALCH-B2TK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 41.5 years (15,170 days).
Specimen ALCH-B2TK-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 35c63209-4b81-460e-9c8a-a0b88600951a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2TK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/98267d7f-adca-499c-b341-1ad21efcf717

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 4,736; copy number 2: 50,236; copy number 3: 2,719; copy number 4: 694; copy number 5: 11; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:222,477,252–222,504,622, 2 genes: AL513314.2, RNU6-791P.
- chr17:14,295,512–14,297,600, 1 gene: AC005224.1.
- chr17:14,303,854–14,305,505, 1 gene (within-gene range 0–2): AC005224.3.
- chr18:59,267,035–59,274,086, 1 gene: RAX.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:51,599,723–52,087,613, 3 genes, copy number 5: AL355997.1, PKHD1, RN7SL580P.
- chr16:32,475,051–32,478,250, 1 gene, copy number 6: ABCD1P3.
- chr16:32,715,931–32,788,944, 8 genes, copy number 5: AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.

Autosomal genes at a single copy (total copy number 1): 2,521. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
